Somatic mutation profile of cancer-model specimen HCM-BROD-0099-C15-85B (3D Organoid, passage 11; aliquot HCM-BROD-0099-C15-85B-01D-A85K-36), derived from the primary tumor of HCMI case HCM-BROD-0099-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 57.2 years (20,880 days).
Specimen HCM-BROD-0099-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbfd4965-6239-4afb-ade7-f439135b5323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0099-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0099-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e3efff2-9875-4f14-932e-127dcdf9f77c

The open-access MAF lists 1,572 somatic variants for this specimen: 1,186 protein-altering or splice-affecting, 327 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 777, Silent 327, Frame Shift Del 201, Frame Shift Ins 145, Nonsense Mutation 28, Intron 27, In Frame Del 13, 3'UTR 11, 5'UTR 10, Splice Region 8, Splice Site 8, 5'Flank 7.

Variants (750 of 1,572; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 100/247 reads (40%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 144/316 reads (46%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CPLANE1 | c.*1148del | 3'UTR (DEL) | VAF 88/257 reads (34%) | catalogued as rs777686211; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 51/434 reads (12%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 106/212 reads (50%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 175/316 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1577del p.G526Afs*74 | Frame Shift Del (DEL) | VAF 218/571 reads (38%) | catalogued as rs794729217; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 181/358 reads (51%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 47/282 reads (17%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- NBN | c.1396dup p.R466Kfs*5 | Frame Shift Ins (INS) | VAF 88/264 reads (33%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 166/431 reads (39%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRL | c.104dup p.T36Yfs*20 | Frame Shift Ins (INS) | VAF 338/784 reads (43%) | catalogued as rs1566561006; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 162/350 reads (46%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- TALDO1 | c.512_514del p.S171del | In Frame Del (DEL) | VAF 188/192 reads (98%) | catalogued as rs137853085; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 638/909 reads (70%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AACS | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751011092; called by muse, mutect2, varscan2
- ABCA10 | c.941dup p.I315Hfs*5 | Frame Shift Ins (INS) | VAF 127/335 reads (38%) | catalogued as rs771346448; called by mutect2, pindel, varscan2
- ABCC12 | c.2317dup p.Q773Pfs*15 | Frame Shift Ins (INS) | VAF 188/368 reads (51%) | catalogued as rs868446631; called by mutect2, varscan2
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 212/454 reads (47%) | catalogued as rs750897785; called by mutect2, varscan2
- AC006059.2 | c.1109dup p.K371Efs*15 | Frame Shift Ins (INS) | VAF 178/449 reads (40%) | catalogued as rs1175736292; called by mutect2, pindel, varscan2
- AC009412.1 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 234/516 reads (45%) | SIFT deleterious (0); catalogued as COSV57626962; called by muse, varscan2
- ACIN1 | c.1762A>G p.S588G | Missense Mutation (SNP) | VAF 38/457 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs760865737; called by muse, mutect2
- ACP6 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 231/443 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781901499, COSV65077762; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 274/284 reads (96%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 116/257 reads (45%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS8 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 351/684 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs772968405; called by muse, mutect2, varscan2
- ADAMTSL4 | c.745dup p.L249Pfs*52 | Frame Shift Ins (INS) | VAF 146/442 reads (33%) | catalogued as rs761084716; called by mutect2, pindel, varscan2
- ADGB | c.3247C>T p.R1083C | Missense Mutation (SNP) | VAF 169/369 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1274771179; called by muse, mutect2, varscan2
- ADGRA1 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 323/610 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV101658597; called by muse, mutect2, varscan2
- ADGRA1 | c.1371dup p.S458Qfs*31 | Frame Shift Ins (INS) | VAF 332/680 reads (49%) | catalogued as rs1202605317; called by mutect2, varscan2
- ADRA2A | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 262/499 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529431; called by mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 449/678 reads (66%) | catalogued as rs748399150; called by mutect2, varscan2
- AHCTF1 | c.1187G>A p.R396Q (on ENST00000366508; = p.R370Q on NM_015446.5) | Missense Mutation (SNP) | VAF 139/311 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs768685968; called by muse, mutect2, varscan2
- AHNAK | c.15185T>A p.V5062D | Missense Mutation (SNP) | VAF 275/552 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57225331; called by muse, mutect2, varscan2
- AKAP17A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 368/832 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV58312219; called by muse, mutect2, varscan2
- AKAP17A | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 408/808 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1376345456; called by muse, mutect2, varscan2
- AKAP6 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 149/399 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs539925484, COSV55207514; called by muse, mutect2, varscan2
- ALDH16A1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 545/546 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs1015091964; called by muse, mutect2, varscan2
- AMER2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 208/399 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs777199055; called by muse, mutect2, varscan2
- AMH | c.914dup p.A306Gfs*77 | Frame Shift Ins (INS) | VAF 289/771 reads (37%) | catalogued as rs1377795855; called by mutect2, pindel, varscan2
- ANKRD31 | c.4273dup p.I1425Nfs*9 | Frame Shift Ins (INS) | VAF 168/350 reads (48%) | catalogued as rs1233667551; called by mutect2, varscan2
- ANKS1B | c.2884A>G p.R962G (on ENST00000547776 / NM_152788.4; = p.R188G on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/305 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs993414900, COSV59124016; called by muse, mutect2, varscan2
- AOX1 | c.1141T>G p.L381V | Missense Mutation (SNP) | VAF 115/431 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV65980613; called by muse, mutect2, varscan2
- AP5M1 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1243464603; called by muse, mutect2
- AP5S1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs777244137, COSV55694279; called by muse, mutect2, varscan2
- AP5Z1 | c.2086del p.Q696Rfs*6 | Frame Shift Del (DEL) | VAF 266/537 reads (50%) | catalogued as rs771683676, COSV100804281; called by mutect2, varscan2
- ARAP1 | c.3905G>A p.R1302H (on ENST00000393609 / NM_001040118.2; = p.R1057H on NM_015242.4) | Missense Mutation (SNP) | VAF 259/506 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754149945, COSV61993674; called by muse, mutect2, varscan2
- ARAP2 | c.4336_4338del p.E1446del | In Frame Del (DEL) | VAF 110/280 reads (39%) | catalogued as rs775660152; called by pindel, varscan2
- ARHGAP18 | c.488del p.N163Tfs*55 | Frame Shift Del (DEL) | VAF 161/365 reads (44%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGAP20 | c.3367A>G p.S1123G | Missense Mutation (SNP) | VAF 90/406 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52806782; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 744/1049 reads (71%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP8B4 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755705346; called by muse, mutect2, varscan2
- BABAM2 | c.488dup p.N163Kfs*6 | Frame Shift Ins (INS) | VAF 67/146 reads (46%) | catalogued as rs373964958; called by mutect2, varscan2
- BAZ1B | c.4364A>G p.K1455R | Missense Mutation (SNP) | VAF 104/537 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1554565213, COSV59995733; called by muse, mutect2, varscan2
- BCL9L | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 398/774 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52685927; called by muse, mutect2, varscan2
- BCOR | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 295/295 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs778129253, COSV60719250; called by muse, mutect2, varscan2
- BEND4 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 172/365 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as rs538291585; called by muse, mutect2, varscan2
- BICC1 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 213/415 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1249340038; called by muse, mutect2, varscan2
- BLNK | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 326/617 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV99814109; called by muse, mutect2, varscan2
- BRWD1 | c.5446dup p.T1816Nfs*6 | Frame Shift Ins (INS) | VAF 151/303 reads (50%) | catalogued as rs1568856013; called by mutect2, varscan2
- BTN3A2 | c.949del p.I317Sfs*4 | Frame Shift Del (DEL) | VAF 185/442 reads (42%) | catalogued as COSV62687981; called by mutect2, pindel, varscan2
- C21orf91 | c.799G>A p.V267I (on ENST00000284881 / NM_001100420.2; = p.V266I on NM_017447.4) | Missense Mutation (SNP) | VAF 182/388 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752922725, COSV53033144; called by muse, varscan2
- C4orf54 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 224/414 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs866088896; called by muse, mutect2, varscan2
- C5orf38 | c.226del p.D76Mfs*5 | Frame Shift Del (DEL) | VAF 177/583 reads (30%) | catalogued as rs746245907, COSV57410849; called by mutect2, pindel, varscan2
- CACNA1B | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 104/537 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1220879681; called by muse, mutect2, varscan2
- CACNA1F | c.3814A>G p.T1272A | Missense Mutation (SNP) | VAF 270/271 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs1557106783; called by muse, mutect2, varscan2
- CACNA1G | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 176/347 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1478327583, COSV100661242; called by muse, mutect2, varscan2
- CACNA1H | c.3581G>A p.R1194Q | Missense Mutation (SNP) | VAF 242/736 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs759668583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.5209G>A p.A1737T | Missense Mutation (SNP) | VAF 328/487 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs61372944, COSV100673569; called by muse, mutect2, varscan2
- CADM2 | c.234G>T p.E78D (on ENST00000407528 / NM_001167674.2; = p.E80D on NM_153184.4) | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101054730; called by muse, mutect2
- CAMTA1 | c.303A>G p.R101= | Splice Region (SNP) | VAF 120/227 reads (53%) | catalogued as rs1235140468; called by muse, mutect2, varscan2
- CAPG | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99809370; called by muse, mutect2, varscan2
- CARD14 | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 347/738 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100413504; called by muse, mutect2, varscan2
- CASZ1 | c.4601G>A p.R1534H | Missense Mutation (SNP) | VAF 20/650 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1299223191, COSV65457715; called by muse, mutect2
- CBX2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 291/616 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs1351261350; called by muse, mutect2, varscan2
- CCDC137 | c.495del p.A166Rfs*7 | Frame Shift Del (DEL) | VAF 123/325 reads (38%) | catalogued as rs1435124182; called by mutect2, pindel, varscan2
- CCR6 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 202/453 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs201556077, COSV100551020, COSV59474209, COSV59475783; called by muse, mutect2, varscan2
- CDADC1 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as rs141868508; called by muse, mutect2, varscan2
- CDH9 | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 67/609 reads (11%) | catalogued as COSV99141391; called by muse, mutect2, varscan2
- CDKL1 | c.22del p.I8Lfs*38 | Frame Shift Del (DEL) | VAF 135/380 reads (36%) | catalogued as rs1566616984; called by mutect2, pindel, varscan2
- CDON | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761883698, COSV99700812; called by muse, mutect2, varscan2
- CDYL | c.1702G>A p.E568K (on ENST00000328908 / NM_001368125.1; = p.E514K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/453 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs748790925; called by muse, mutect2, varscan2
- CELSR1 | c.3895del p.V1299Cfs*18 | Frame Shift Del (DEL) | VAF 69/617 reads (11%) | catalogued as COSV99418345; called by mutect2, pindel, varscan2
- CELSR3 | c.7714C>T p.R2572C | Missense Mutation (SNP) | VAF 315/648 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs759393208, COSV50842866; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 66/152 reads (43%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP250 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 49/612 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs769794651; called by muse, mutect2
- CLCN1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 190/356 reads (53%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201327261; called by muse, mutect2, varscan2
- CLK3 | c.1225C>T p.R409W (on ENST00000395066 / NM_001130028.1; = p.R261W on NM_003992.4) | Missense Mutation (SNP) | VAF 203/470 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs1159353958; called by muse, mutect2
- CLSPN | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs760376374; called by muse, mutect2, varscan2
- CNTLN | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 159/332 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.586); catalogued as COSV52087517; called by muse, mutect2, varscan2
- CNTRL | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as rs1481124718; called by muse, mutect2, varscan2
- COL7A1 | c.7987del p.E2663Sfs*16 | Frame Shift Del (DEL) | VAF 82/599 reads (14%) | catalogued as CM096538; called by mutect2, pindel, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 122/327 reads (37%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- COX7A2 | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1287771274; called by muse, mutect2, varscan2
- CPLX2 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1217258172, COSV63999590; called by muse, mutect2, varscan2
- CRYBG1 | c.620del p.P207Lfs*29 | Frame Shift Del (DEL) | VAF 303/788 reads (38%) | catalogued as rs1018039182; called by mutect2, pindel, varscan2
- CSMD3 | c.10460A>G p.K3487R (on ENST00000297405 / NM_001363185.1; = p.K3318R on NM_052900.3) | Missense Mutation (SNP) | VAF 125/443 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV52183546; called by muse, mutect2, varscan2
- CTC1 | c.3367G>A p.G1123R | Missense Mutation (SNP) | VAF 148/302 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1336846960; called by muse, mutect2, varscan2
- CTSK | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 143/367 reads (39%) | catalogued as rs764168526; called by mutect2, pindel, varscan2
- CWC15 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1355194236, COSV99688675; called by muse, mutect2, varscan2
- CYP1A2 | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 218/534 reads (41%) | catalogued as rs1476915394; called by muse, mutect2, varscan2
- CYSLTR2 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375669186; called by muse, mutect2, varscan2
- DAB1 | c.885del p.T296Lfs*70 (on ENST00000371231; = p.T263Lfs*70 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 176/397 reads (44%) | catalogued as COSV104428367; called by mutect2, pindel, varscan2
- DCAF12L1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284451282, COSV64422872; called by muse, mutect2, varscan2
- DCDC2C | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 334/633 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs960748580; called by muse, mutect2, varscan2
- DCHS1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 296/299 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760313532; called by muse, varscan2
- DDHD1 | c.990A>C p.K330N (on ENST00000323669; = p.K527N on NM_030637.3) | Missense Mutation (SNP) | VAF 186/393 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV60362049; called by muse, mutect2, varscan2
- DDX55 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 57/299 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1440099279; called by muse, mutect2, varscan2
- DGKE | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs547304654; called by muse, mutect2, varscan2
- DIPK1B | c.673T>C p.C225R | Missense Mutation (SNP) | VAF 332/666 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964835698; called by muse, mutect2, varscan2
- DLGAP4 | c.2825G>A p.R942H (on ENST00000339266 / NM_001365621.1; = p.R939H on NM_014902.6) | Missense Mutation (SNP) | VAF 478/715 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757785334, COSV59414319; called by muse, mutect2, varscan2
- DNAH6 | c.9553A>G p.K3185E | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52873786; called by muse, mutect2
- DOCK1 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 46/512 reads (9%) | catalogued as COSV99732987; called by muse, mutect2
- DPH5 | c.623_625del p.G208del | In Frame Del (DEL) | VAF 98/220 reads (45%) | catalogued as rs779889468; called by pindel, varscan2
- DPP6 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1263209878; called by muse, mutect2, varscan2
- DRC1 | c.1851del p.W618Gfs*19 | Frame Shift Del (DEL) | VAF 219/544 reads (40%) | catalogued as rs781097632, COSV55514089; called by mutect2, pindel, varscan2
- DSCAM | c.5628del p.K1877Nfs*8 | Frame Shift Del (DEL) | VAF 241/577 reads (42%) | catalogued as rs766229789; called by mutect2, pindel, varscan2
- DTX2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 175/715 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs764883046, COSV56859892; called by muse, mutect2, varscan2
- DYNC1H1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 137/276 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs201746558, COSV64134550; called by muse, mutect2, varscan2
- DZIP1 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 239/468 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.196); catalogued as rs756850664; called by muse, mutect2, varscan2
- EBF2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 39/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750959333, COSV68780935; called by muse, mutect2
- EFCAB5 | c.437dup p.A147Gfs*2 | Frame Shift Ins (INS) | VAF 148/325 reads (46%) | catalogued as rs767553068; called by mutect2, varscan2
- EHBP1 | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 197/430 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.285); catalogued as COSV50431558; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 92/222 reads (41%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF5 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 159/380 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53684838, COSV53685476; called by muse, mutect2, varscan2
- EPHA3 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 149/316 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60700624; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 61/354 reads (17%) | catalogued as rs1317589623; called by mutect2, pindel, varscan2
- EPHA5 | c.1203T>G p.H401Q | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV99895785; called by muse, varscan2
- EPHB6 | c.760dup p.A254Gfs*71 | Frame Shift Ins (INS) | VAF 334/718 reads (47%) | catalogued as rs756241644; called by mutect2, varscan2
- EPHX1 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 178/336 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771190130; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 118/404 reads (29%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN2 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs1313282622; called by muse, mutect2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, mutect2, varscan2
- ESPNL | c.719C>G p.A240G | Missense Mutation (SNP) | VAF 657/659 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58037116; called by muse, mutect2, varscan2
- EYS | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs980927028; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 118/210 reads (56%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM186B | c.1546_1548del p.E516del | In Frame Del (DEL) | VAF 283/626 reads (45%) | catalogued as rs1445707432; called by mutect2, pindel, varscan2
- FAM20A | c.129del p.C44Afs*101 | Frame Shift Del (DEL) | VAF 282/722 reads (39%) | catalogued as rs1567756818; called by mutect2, pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 268/691 reads (39%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM91A1 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 348/554 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58238025; called by muse, varscan2
- FANCE | c.544del p.Q182Rfs*114 | Frame Shift Del (DEL) | VAF 216/552 reads (39%) | catalogued as rs1561789651, COSV100003664; called by mutect2, pindel, varscan2
- FANCI | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 169/347 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as CM074783; called by muse, mutect2, varscan2
- FAR2 | c.1329del p.K443Nfs*4 | Frame Shift Del (DEL) | VAF 140/339 reads (41%) | catalogued as COSV99479542; called by mutect2, pindel, varscan2
- FBXL19 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 302/637 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1399898651; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 131/312 reads (42%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FER1L5 | c.3259C>T p.P1087S (on ENST00000623019; = p.P1060S on NM_001293083.2) | Missense Mutation (SNP) | VAF 233/530 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as rs1305696916; called by muse, mutect2, varscan2
- FERMT1 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 187/471 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs770476471; called by muse, mutect2
- FGR | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 240/525 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100925930; called by muse, mutect2, varscan2
- FLG | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 202/423 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs756351291, COSV64235927; called by mutect2, varscan2
- FLYWCH1 | c.742del p.R248Efs*6 (on ENST00000253928 / NM_001308068.2; = p.R247Efs*6 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 269/677 reads (40%) | catalogued as COSV54147393; called by mutect2, pindel, varscan2
- FMN2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 59/554 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs771825158; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 310/787 reads (39%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FOSB | c.822del p.N275Tfs*2 | Frame Shift Del (DEL) | VAF 395/959 reads (41%) | catalogued as COSV62279449; called by mutect2, pindel, varscan2
- FOXF1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 277/576 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1293500536, COSV52285464; called by muse, mutect2, varscan2
- FOXI1 | c.78dup p.E27Rfs*7 | Frame Shift Ins (INS) | VAF 219/374 reads (59%) | catalogued as rs776996183; called by pindel, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 290/304 reads (95%) | catalogued as rs755234663; called by mutect2, varscan2
- FZD1 | c.794dup p.A266Rfs*36 | Frame Shift Ins (INS) | VAF 255/490 reads (52%) | catalogued as rs778939413; called by mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 164/416 reads (39%) | catalogued as rs754177800; called by mutect2, varscan2
- GFM1 | c.843A>G p.L281= | Splice Region (SNP) | VAF 132/266 reads (50%) | catalogued as rs759440642; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFRA4 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 211/430 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1487861516; called by muse, mutect2, varscan2
- GJA8 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 237/556 reads (43%) | catalogued as COSV53789902; called by mutect2, pindel, varscan2
- GLB1L2 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57000524; called by muse, mutect2
- GLG1 | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 195/393 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1244624471; called by muse, mutect2, varscan2
- GLI2 | c.3119A>G p.E1040G (on ENST00000361492 / NM_001374353.1; = p.E1057G on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 397/826 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV58044171; called by muse, mutect2, varscan2
- GLI3 | c.3031A>G p.T1011A | Missense Mutation (SNP) | VAF 145/744 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs1397866934; called by muse, mutect2, varscan2
- GPRASP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 316/316 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781232292, COSV100851060; called by muse, mutect2, varscan2
- GRAMD2B | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1052869985; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 187/196 reads (95%) | catalogued as rs760757380; called by mutect2, varscan2
- GRXCR2 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 239/492 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244490927; called by muse, mutect2, varscan2
- GTF2F2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs746742188; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 194/564 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs1554454661; called by muse, mutect2, varscan2
- GTF3C1 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1177923658; called by muse, mutect2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 136/284 reads (48%) | catalogued as COSV54945907; called by mutect2, varscan2
- H1-7 | c.306del p.Q103Rfs*119 | Frame Shift Del (DEL) | VAF 58/616 reads (9%) | catalogued as rs771422460; called by mutect2, pindel, varscan2
- HADHA | c.2219A>G p.Y740C | Missense Mutation (SNP) | VAF 298/580 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66108303; called by muse, mutect2, varscan2
- HECW1 | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs781554844; called by muse, mutect2, varscan2
- HIF1A | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs755629700, COSV60192627; called by muse, mutect2, varscan2
- HK1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 255/533 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs148472311; called by muse, mutect2, varscan2
- HM13 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 361/1099 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1300852357; called by muse, mutect2, varscan2
- HOXA3 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 146/352 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746664809; called by muse, mutect2, varscan2
- HTATSF1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54479699; called by muse, varscan2
- IDE | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1394653409; called by muse, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 226/234 reads (97%) | catalogued as rs750779916, COSV60737300; called by mutect2, varscan2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 80/195 reads (41%) | catalogued as rs979653918; called by mutect2, varscan2
- IFT46 | c.898A>G p.T300A (on ENST00000264021 / NM_001168618.2; = p.T351A on NM_020153.3) | Missense Mutation (SNP) | VAF 175/359 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs782548690; called by muse, mutect2, varscan2
- IGFBP4 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 251/550 reads (46%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV54098643; called by muse, mutect2, varscan2
- IGFBPL1 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 216/436 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1419174396; called by muse, varscan2
- IGHV1-2 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 179/396 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs557034159; called by muse, mutect2, varscan2
- IGLV3-27 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 227/446 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1437035494; called by muse, mutect2, varscan2
- IGSF3 | c.1978C>T p.R660* (on ENST00000369486 / NM_001007237.3; = p.R680* on NM_001542.4) | Nonsense Mutation (SNP) | VAF 236/562 reads (42%) | catalogued as COSV59595185; called by muse, mutect2, varscan2
- IL6R | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 183/415 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468329259; called by muse, mutect2, varscan2
- IRS2 | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 394/787 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.275); catalogued as rs545026034; called by muse, mutect2, varscan2
- IRX4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 170/902 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51475035, COSV99181922; called by muse, mutect2, varscan2
- JMJD1C | c.6075dup p.E2026Rfs*8 | Frame Shift Ins (INS) | VAF 108/192 reads (56%) | catalogued as rs1226801045; called by mutect2, varscan2
- KCNB2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 642/847 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049052; called by muse, mutect2, varscan2
- KCNQ3 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 420/640 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66470464; called by muse, mutect2, varscan2
- KCNS3 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 228/461 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs140699625; called by muse, mutect2, varscan2
- KDM2B | c.77dup p.K27Efs*10 | Frame Shift Ins (INS) | VAF 176/397 reads (44%) | catalogued as rs782541016; called by mutect2, varscan2
- KDM3A | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 78/341 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200618359, COSV57217731; called by muse, mutect2, varscan2
- KEL | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 104/479 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs199509304, COSV62336463; called by muse, mutect2, varscan2
- KIAA0513 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs888927602, COSV99260898; called by muse, mutect2, varscan2
- KIAA2013 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 256/506 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs145156794; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 107/274 reads (39%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIT | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 132/382 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55386835; called by muse, mutect2, varscan2
- KLHL36 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 306/638 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs754689351; called by muse, mutect2
- KMT2C | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 92/834 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51383526; called by muse, varscan2
- KRT75 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52875262; called by muse, mutect2, varscan2
- KRTAP10-8 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs991800614, COSV58166303; called by muse, mutect2, varscan2
- KRTAP29-1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 334/732 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV66939773; called by muse, mutect2, varscan2
- L1TD1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs375545502; called by muse, mutect2, varscan2
- LAMB2 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 197/449 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs1380503405; called by muse, mutect2, varscan2
- LANCL2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 181/392 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV54652115; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 142/197 reads (72%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDHD | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 304/595 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1233919146, COSV55581830; called by muse, mutect2, varscan2
- LMNB2 | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57591070; called by muse, mutect2, varscan2
- LMTK2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 198/466 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs747890701, COSV99807036; called by muse, mutect2
- LRFN2 | c.479A>C p.N160T | Missense Mutation (SNP) | VAF 209/453 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs76425995; called by muse, mutect2, varscan2
- LRP12 | c.1351dup p.C451Lfs*9 | Frame Shift Ins (INS) | VAF 159/477 reads (33%) | catalogued as rs35928649; called by mutect2, varscan2
- LRP1B | c.11042G>A p.C3681Y | Missense Mutation (SNP) | VAF 17/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67275487; called by muse, mutect2
- LRRC37B | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 62/458 reads (14%) | catalogued as rs771436560; called by muse, mutect2, varscan2
- LRRC42 | c.1187T>C p.F396S | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV59961776; called by muse, mutect2, varscan2
- LRRC8C | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 130/266 reads (49%) | catalogued as rs746628711, COSV64996251; called by muse, mutect2, varscan2
- LRRCC1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 192/293 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV99066558; called by muse, mutect2, varscan2
- LRRIQ1 | c.1544C>G p.S515C | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV67828792; called by muse, mutect2, varscan2
- LRRK2 | c.2756A>G p.D919G | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1312779682; called by muse, mutect2, varscan2
- LRRTM1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 268/553 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs528982180; called by muse, mutect2, varscan2
- LRRTM1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 248/484 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0.085); catalogued as COSV99701961; called by muse, mutect2, varscan2
- LTBP3 | c.3910T>C p.*1304Rext*12 (on ENST00000301873 / NM_001130144.3; = p.*1257Rext*12 on NM_021070.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 250/522 reads (48%) | catalogued as rs1259084776; called by muse, mutect2, varscan2
- MACF1 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 101/402 reads (25%) | catalogued as rs1204948099; called by muse, mutect2, varscan2
- MAN1C1 | c.1296del p.L433* | Frame Shift Del (DEL) | VAF 58/551 reads (11%) | catalogued as rs759630213; called by mutect2, pindel, varscan2
- MAP3K4 | c.4635G>A p.W1545* | Nonsense Mutation (SNP) | VAF 124/244 reads (51%) | catalogued as COSV62336676; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 422/787 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV50498539; called by muse, mutect2
- MAST3 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53221464; called by muse, mutect2, varscan2
- MBD6 | c.2080dup p.Q694Pfs*23 | Frame Shift Ins (INS) | VAF 57/134 reads (43%) | catalogued as rs762648935; called by mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 150/420 reads (36%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MEOX2 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 188/415 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs1297638941; called by muse, mutect2, varscan2
- METTL14 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 142/286 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV66311386; called by muse, mutect2, varscan2
- MICALL2 | c.1211dup p.A405Sfs*15 | Frame Shift Ins (INS) | VAF 244/506 reads (48%) | catalogued as rs767131208; called by mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 111/228 reads (49%) | catalogued as COSV67083276; called by mutect2, varscan2
- MMP25 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 308/624 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100339469; called by muse, varscan2
- MMRN2 | c.2284A>G p.M762V | Missense Mutation (SNP) | VAF 255/523 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1298885800; called by muse, mutect2, varscan2
- MORC4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 91/132 reads (69%) | catalogued as rs759643903; called by mutect2, pindel, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 187/451 reads (41%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRPL4 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 273/555 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1215912278, COSV53449697; called by muse, mutect2, varscan2
- MS4A15 | c.475A>G p.M159V (on ENST00000405633 / NM_001098835.2; = p.M66V on NM_152717.3) | Missense Mutation (SNP) | VAF 190/362 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.127); catalogued as rs1178482302; called by muse, mutect2, varscan2
- MSANTD1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 338/704 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.191); catalogued as rs921891304; called by muse, mutect2, varscan2
- MTMR12 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 208/630 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs754133953, COSV53784261; called by muse, mutect2, varscan2
- MUL1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs558469333, COSV51642966; called by muse, mutect2, varscan2
- MUTYH | c.498G>A p.E166= | Splice Region (SNP) | VAF 181/392 reads (46%) | catalogued as rs764546111; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH1 | c.4181A>C p.K1394T | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56850067; called by muse, mutect2
- MYO15A | c.8064del p.W2689Gfs*49 | Frame Shift Del (DEL) | VAF 55/392 reads (14%) | catalogued as rs1567654864, COSV52756540; called by mutect2, pindel, varscan2
- MYPN | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 258/531 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs529221329, COSV100589576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NALCN | c.2362G>T p.D788Y | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV51964021; called by muse, mutect2, varscan2
- NAPRT | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 586/1188 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs774761219, COSV52782619; called by muse, mutect2, varscan2
- NAV1 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 238/493 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs766634119, COSV55228191; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 400/562 reads (71%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NELFCD | c.287A>G p.Y96C (on ENST00000602795; = p.Y78C on NM_198976.4) | Missense Mutation (SNP) | VAF 191/578 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753983399; called by muse, mutect2, varscan2
- NFIC | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 145/702 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1175118397; called by muse, mutect2, varscan2
- NLE1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 166/310 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs144949018; called by muse, mutect2, varscan2
- NLRP7 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 755/797 reads (95%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs746988595, COSV60175739; called by muse, mutect2, varscan2
- NOTCH1 | c.5282G>A p.R1761Q | Missense Mutation (SNP) | VAF 322/689 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs750318685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH4 | c.1044del p.G349Afs*49 | Frame Shift Del (DEL) | VAF 334/907 reads (37%) | catalogued as rs753855314, COSV66678383, COSV66681385; called by mutect2, pindel, varscan2
- NOXA1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 220/415 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs777037361; called by muse, mutect2, varscan2
- NRXN3 | c.343G>A p.V115M (on ENST00000557594 / NM_001272020.2; = p.V747M on NM_004796.6) | Missense Mutation (SNP) | VAF 275/525 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs982170073, COSV55336026; called by muse, mutect2, varscan2
- NUP210 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 201/387 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs373258255; called by muse, mutect2, varscan2
- OBSCN | c.13108G>A p.A4370T | Missense Mutation (SNP) | VAF 380/752 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs534557072, COSV52833769; called by muse, mutect2, varscan2
- OCEL1 | c.115del p.R39Afs*11 | Frame Shift Del (DEL) | VAF 306/709 reads (43%) | catalogued as COSV99285799; called by mutect2, pindel, varscan2
- OR10W1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 225/470 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR4C15 | c.940C>A p.P314T (on ENST00000314644; = p.P260T on NM_001001920.2) | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs758487234; called by muse, mutect2, varscan2
- OR51T1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 233/236 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs781697460, COSV59025275; called by muse, mutect2, varscan2
- ORC6 | c.507dup p.A170Sfs*4 | Frame Shift Ins (INS) | VAF 134/286 reads (47%) | catalogued as rs35441257; called by mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 144/153 reads (94%) | catalogued as rs750679212; called by mutect2, varscan2
- PALD1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 233/512 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1247625775; called by muse, mutect2, varscan2
- PARP9 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 194/380 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760164261; called by muse, mutect2
- PARPBP | c.662T>C p.F221S | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59677517; called by muse, mutect2, varscan2
- PBXIP1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 72/672 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63777063; called by muse, mutect2, varscan2
- PCDHA11 | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 248/539 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as rs782114058; called by muse, mutect2, varscan2
- PCDHGA1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 149/297 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); catalogued as COSV65295383, COSV65296145; called by muse, mutect2, varscan2
- PCDHGA12 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 135/295 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs767521224, COSV52741799; called by muse, mutect2, varscan2
- PCDHGA7 | c.369A>G p.I123M | Missense Mutation (SNP) | VAF 141/286 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs773903039; called by muse, mutect2, varscan2
- PDLIM1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as rs370809135; called by muse, mutect2
- PDLIM4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 277/527 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as rs867265087, COSV53803954, COSV99516804; called by muse, mutect2, varscan2
- PDPN | c.274G>A p.A92T (on ENST00000621990; = p.A168T on NM_006474.4) | Missense Mutation (SNP) | VAF 140/291 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs532394472, COSV53850814; called by muse, mutect2, varscan2
- PDZD9 | c.518A>G p.H173R (on ENST00000424898 / NM_001363519.1; = p.H113R on NM_173806.4) | Missense Mutation (SNP) | VAF 228/446 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1305866132; called by muse, mutect2, varscan2
- PDZRN4 | c.395dup p.C133Lfs*89 | Frame Shift Ins (INS) | VAF 70/164 reads (43%) | catalogued as rs1203008747; called by mutect2, varscan2
- PGAP6 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 168/559 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as rs768450549, COSV51741052; called by muse, varscan2
- PHACTR3 | c.695del p.P232Hfs*30 | Frame Shift Del (DEL) | VAF 501/958 reads (52%) | catalogued as COSV63028198; called by mutect2, pindel, varscan2
- PIH1D1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as COSV51807016; called by muse, mutect2, varscan2
- PIK3CB | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV56687321; called by muse, mutect2, varscan2
- PKD1L1 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs367553671; called by mutect2, varscan2
- PLD3 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 635/635 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs940601505, COSV99396458; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 156/164 reads (95%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHH1 | c.3999dup p.T1334Hfs*56 | Frame Shift Ins (INS) | VAF 215/467 reads (46%) | catalogued as rs761759640; called by mutect2, varscan2
- POGK | c.689del p.N230Tfs*8 | Frame Shift Del (DEL) | VAF 199/455 reads (44%) | catalogued as COSV63312096; called by mutect2, pindel, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 126/257 reads (49%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- PPARA | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 282/584 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766370613, COSV53079008, COSV53080338; called by muse, mutect2
- PPM1K | c.462_464del p.K154del | In Frame Del (DEL) | VAF 116/292 reads (40%) | catalogued as rs1269842628; called by pindel, varscan2
- PPME1 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 172/348 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs148853537; called by muse, mutect2, varscan2
- PPP1R13L | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 383/383 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1473770382; called by muse, mutect2, varscan2
- PPP1R16A | c.1333dup p.H445Pfs*14 | Frame Shift Ins (INS) | VAF 311/1622 reads (19%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PREX2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 127/474 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866864487, COSV55780007; called by muse, mutect2, varscan2
- PROS1 | c.563del p.N188Mfs*20 | Frame Shift Del (DEL) | VAF 103/277 reads (37%) | catalogued as rs753544869; called by mutect2, pindel, varscan2
- PSD | c.750dup p.S251Qfs*5 | Frame Shift Ins (INS) | VAF 160/340 reads (47%) | catalogued as rs761494960; called by mutect2, varscan2
- PTPRF | c.5364G>A p.R1788= | Splice Region (SNP) | VAF 140/297 reads (47%) | catalogued as rs1324438993; called by muse, mutect2, varscan2
- PTPRQ | c.5901dup p.A1968Cfs*24 (on ENST00000616559; = p.A1926Cfs*24 on NM_001145026.2) | Frame Shift Ins (INS) | VAF 133/356 reads (37%) | catalogued as rs1174298545; called by mutect2, pindel, varscan2
- PTPRT | c.2598A>T p.Q866H | Missense Mutation (SNP) | VAF 255/738 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61978809; called by muse, mutect2, varscan2
- QARS1 | c.633C>T p.G211= | Splice Region (SNP) | VAF 164/338 reads (49%) | catalogued as rs752655908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB10 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs758384060; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 132/248 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52966810; called by mutect2, varscan2
- RABEP2 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 409/729 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs775196829; called by muse, mutect2, varscan2
- RAG2 | c.1524dup p.G509Rfs*15 | Frame Shift Ins (INS) | VAF 173/248 reads (70%) | catalogued as rs751978214; called by mutect2, pindel, varscan2
- RALYL | c.366C>T p.G122= | Splice Region (SNP) | VAF 104/378 reads (28%) | catalogued as rs182622234, COSV72818112; called by muse, mutect2, varscan2
- RASA3 | c.1370_1372del p.F457del | In Frame Del (DEL) | VAF 161/385 reads (42%) | catalogued as rs767949177; called by pindel, varscan2
- RBM20 | c.1222del p.L408Sfs*17 | Frame Shift Del (DEL) | VAF 223/568 reads (39%) | catalogued as COSV65704142; called by mutect2, pindel, varscan2
- RCBTB2 | c.298dup p.I100Nfs*27 | Frame Shift Ins (INS) | VAF 151/336 reads (45%) | catalogued as rs767856805; called by mutect2, varscan2
- RCCD1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs139606108; called by muse, mutect2, varscan2
- RFC1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 115/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376166947; called by muse, mutect2, varscan2
- RFX7 | c.2777C>T p.P926L (on ENST00000559447 / NM_001368074.1; = p.P1023L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428385, COSV57963129; called by muse, mutect2, varscan2
- RGL4 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 216/426 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs374014694; called by muse, mutect2, varscan2
- RHBDD3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 356/742 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs530526042; called by muse, mutect2, varscan2
- RHBDF2 | c.932dup p.L312Tfs*52 | Frame Shift Ins (INS) | VAF 178/442 reads (40%) | catalogued as rs756639910; called by mutect2, varscan2
- RILP | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 84/627 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs750685599, COSV53957445, COSV53957810; called by muse, mutect2, varscan2
- RIPK4 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 214/435 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171215367; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 246/632 reads (39%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT1 | c.704del p.L235* | Frame Shift Del (DEL) | VAF 89/225 reads (40%) | catalogued as COSV59869927; called by mutect2, pindel, varscan2
- ROGDI | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 280/534 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762068973; called by muse, mutect2, varscan2
- RREB1 | c.3907C>T p.R1303C | Missense Mutation (SNP) | VAF 289/613 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1308515141; called by muse, mutect2, varscan2
- RS1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 140/185 reads (76%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs374672514, COSV66105794; called by muse, mutect2, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 180/398 reads (45%) | catalogued as rs771992011; called by mutect2, varscan2
- RYR2 | c.14368C>T p.R4790* | Nonsense Mutation (SNP) | VAF 116/274 reads (42%) | catalogued as COSV63702045; called by muse, varscan2
- SACS | c.11809A>G p.N3937D | Missense Mutation (SNP) | VAF 199/394 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as rs1480129736; called by muse, mutect2, varscan2
- SALL3 | c.906del p.G303Afs*92 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs1424702195; called by pindel, varscan2
- SAMD11 | c.1005dup p.A336Rfs*119 | Frame Shift Ins (INS) | VAF 148/339 reads (44%) | catalogued as rs1410048057; called by mutect2, pindel, varscan2
- SAMD4A | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 171/447 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs778052233, COSV51880189; called by muse, mutect2, varscan2
- SAMHD1 | c.286del p.E96Rfs*20 | Frame Shift Del (DEL) | VAF 184/618 reads (30%) | catalogued as COSV99483707; called by mutect2, pindel, varscan2
- SBSPON | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 159/800 reads (20%) | catalogued as rs750912392, COSV52076656; called by muse, mutect2, varscan2
- SCAF11 | c.3845del p.P1282Lfs*29 | Frame Shift Del (DEL) | VAF 132/330 reads (40%) | catalogued as rs764655538; called by pindel, varscan2
- SCG5 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 289/291 reads (99%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.019); catalogued as rs200869533; called by muse, mutect2, varscan2
- SCN9A | c.4729G>T p.G1577* (on ENST00000303354; = p.G1566* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 42/247 reads (17%) | catalogued as rs1553474173, COSV57615985; called by muse, mutect2, varscan2
- SEC16A | c.1689del p.F563Lfs*9 | Frame Shift Del (DEL) | VAF 53/510 reads (10%) | catalogued as COSV99255876; called by mutect2, pindel, varscan2
- SEC24A | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as rs764642106; called by muse, mutect2, varscan2
- SEC24D | c.2029C>A p.L677I | Missense Mutation (SNP) | VAF 125/259 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1353251933; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as rs751191303; called by mutect2, varscan2
- SERPINB5 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV101237620; called by muse, mutect2, varscan2
- SH2B3 | c.1192C>G p.R398G | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57982559; called by muse, mutect2, varscan2
- SH2D3C | c.2129G>A p.R710Q (on ENST00000314830 / NM_170600.3; = p.R553Q on NM_005489.4) | Missense Mutation (SNP) | VAF 219/478 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs752313584, COSV59126905; called by muse, mutect2, varscan2
- SH3RF2 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751741883; called by muse, mutect2, varscan2
- SHC3 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 298/586 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs746708767; called by muse, varscan2
- SHOC1 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100597555; called by muse, mutect2, varscan2
- SI | c.4432A>G p.R1478G | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175510343; called by muse, mutect2, varscan2
- SIPA1L3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 668/1059 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs767672961, COSV55914125; called by muse, mutect2
- SLC17A2 | c.361dup p.M121Nfs*21 | Frame Shift Ins (INS) | VAF 77/365 reads (21%) | catalogued as rs770669846; called by mutect2, varscan2
- SLC17A7 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 566/566 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs535780422, COSV55546736; called by muse, mutect2, varscan2
- SLC25A32 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 219/639 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as COSV52568760; called by muse, mutect2, varscan2
- SLC38A9 | c.934dup p.S312Ffs*4 | Frame Shift Ins (INS) | VAF 116/244 reads (48%) | catalogued as rs753030864; called by mutect2, varscan2
- SLC7A6 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 316/605 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54718366; called by muse, mutect2, varscan2
- SLC9A3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 223/722 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as rs375784344; called by muse, mutect2, varscan2
- SLF2 | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 190/395 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs770442229, COSV53276063; called by muse, mutect2, varscan2
- SMAD6 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 185/387 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201098141, COSV56597518; called by muse, mutect2, varscan2
- SMG6 | c.2524A>G p.T842A | Missense Mutation (SNP) | VAF 470/470 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs750155315; called by muse, mutect2, varscan2
- SMR3A | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 232/479 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs763076642, COSV56951466; called by muse, mutect2, varscan2
- SNRNP200 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60492629; called by muse, mutect2, varscan2
- SNX15 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 170/418 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs576005811, COSV57246494; called by muse, mutect2, varscan2
- SP140 | c.1420A>T p.S474C | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs200029513; called by muse, mutect2, varscan2
- SPAG17 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 197/391 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs139343615; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 131/314 reads (42%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPATA31A3 | c.3574dup p.T1192Nfs*14 | Frame Shift Ins (INS) | VAF 218/483 reads (45%) | catalogued as rs1301154937; called by mutect2, varscan2
- SPNS2 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 555/557 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779414794, COSV54606682; called by muse, mutect2, varscan2
- SPOCK3 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs755016780; called by muse, mutect2, varscan2
- SPON2 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 312/641 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs1209582870; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 103/232 reads (44%) | catalogued as rs1470980144, COSV72486131; called by mutect2, varscan2
- SRSF6 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 130/417 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs147863077; called by muse, mutect2, varscan2
- SS18L1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 390/643 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59209665, COSV59210948; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 106/113 reads (94%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 154/630 reads (24%) | catalogued as rs746501298; called by mutect2, varscan2
- STRA6 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 292/599 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs140894233; called by muse, mutect2, varscan2
- STRC | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 282/566 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.359); catalogued as rs763225240; called by muse, mutect2, varscan2
- STUM | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1364260453; called by mutect2, varscan2
- SYNPO2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 234/502 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239718386, COSV61114924; called by muse, mutect2, varscan2
- TAF1L | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 230/466 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756820373, COSV54257507, COSV99644464; called by muse, mutect2, varscan2
- TAOK2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 231/525 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs781600192, COSV54234458; called by muse, mutect2, varscan2
- TAOK3 | c.931dup p.I311Nfs*13 | Frame Shift Ins (INS) | VAF 140/314 reads (45%) | catalogued as rs1346340006; called by mutect2, varscan2
- TBC1D16 | c.1513dup p.E505Gfs*43 | Frame Shift Ins (INS) | VAF 131/325 reads (40%) | catalogued as rs759141475; called by mutect2, pindel, varscan2
- TCHH | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 245/521 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs201179054, COSV64276945; called by muse, mutect2, varscan2
- TCHH | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 173/414 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.961); catalogued as COSV64274704; called by muse, mutect2, varscan2
- TENM4 | c.2937C>A p.F979L | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53655939, COSV53661557; called by muse, mutect2, varscan2
- TIGD7 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 211/485 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372035499; called by muse, mutect2, varscan2
- TLE5 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 176/412 reads (43%) | catalogued as rs1225559792; called by muse, mutect2
- TMC3 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1163896188; called by muse, mutect2
- TMEM121B | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 335/698 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs747913031; called by muse, mutect2, varscan2
- TMEM65 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 106/179 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs781601480; called by muse, mutect2, varscan2
- TNKS | c.3662G>A p.S1221N | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60059288; called by muse, varscan2
- TNKS2 | c.1047dup p.H350Tfs*16 | Frame Shift Ins (INS) | VAF 158/466 reads (34%) | catalogued as rs1436960698; called by mutect2, pindel, varscan2
- TNNT2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs763316865; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 142/288 reads (49%) | catalogued as rs770561785; called by mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 218/533 reads (41%) | catalogued as rs770451471, COSV57014685; called by mutect2, pindel, varscan2
- TRIO | c.7050dup p.V2351Rfs*90 | Frame Shift Ins (INS) | VAF 252/509 reads (50%) | catalogued as rs746654944; called by mutect2, varscan2
- TRIO | c.7425dup p.S2476Qfs*49 | Frame Shift Ins (INS) | VAF 226/878 reads (26%) | catalogued as rs774597492; ClinVar: uncertain significance; called by mutect2, varscan2
- TRUB1 | c.595dup p.L199Pfs*20 | Frame Shift Ins (INS) | VAF 124/263 reads (47%) | catalogued as rs762997509; called by mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 243/740 reads (33%) | catalogued as rs1193207010; called by mutect2, varscan2
- TTLL10 | c.362G>A p.R121Q (on ENST00000379289 / NM_001130045.2; = p.R48Q on NM_153254.3) | Missense Mutation (SNP) | VAF 109/799 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs142661836; called by muse, varscan2
- TTN | c.2396C>T p.T799M (on ENST00000591111; = p.T753M on NM_003319.4) | Missense Mutation (SNP) | VAF 250/251 reads (100%) | PolyPhen benign (0.107); catalogued as rs149061352, COSV60000823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH3 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 364/774 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1180699779, COSV51863414; called by muse, mutect2, varscan2
- TUBE1 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 191/382 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782115613; called by muse, mutect2, varscan2
- TUT7 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 233/532 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs766227229; called by muse, mutect2
- UBC | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 193/441 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1442268922; called by muse, mutect2, varscan2
- UBL3 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.092); catalogued as rs562596173; called by muse, mutect2, varscan2
- UGCG | c.1094dup p.L365Ffs*36 | Frame Shift Ins (INS) | VAF 175/408 reads (43%) | catalogued as rs1243652090; called by mutect2, varscan2
- UGGT1 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as rs757746933; called by muse, mutect2, varscan2
- UROC1 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 202/361 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV52034713, COSV99330729; called by muse, mutect2, varscan2
- USH2A | c.4217C>A p.S1406* | Nonsense Mutation (SNP) | VAF 63/324 reads (19%) | catalogued as rs1308702971, COSV56425599; called by muse, mutect2, varscan2
- UST | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 231/496 reads (47%) | catalogued as rs760552029, COSV66551382; called by mutect2, varscan2
- UVSSA | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 243/515 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs188017443, COSV101104352; called by muse, mutect2, varscan2
- VCX2 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.294); catalogued as rs371798479; called by muse, mutect2, varscan2
- VIPAS39 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 126/311 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as rs746475339, COSV58940163; called by muse, mutect2, varscan2
- VIRMA | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 264/796 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV52584375; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 164/327 reads (50%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13B | c.4640T>G p.I1547S | Missense Mutation (SNP) | VAF 423/624 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV62144850; called by muse, mutect2, varscan2
- VPS9D1 | c.1805A>G p.Y602C | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs566042318; called by muse, mutect2, varscan2
- VWC2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 293/613 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs574589537; called by muse, mutect2, varscan2
- VWDE | c.4225A>G p.I1409V | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1247071291; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 106/275 reads (39%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR64 | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 114/239 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1160533747; called by muse, varscan2
- WDR76 | c.817T>C p.W273R | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs778295157; called by muse, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 292/773 reads (38%) | catalogued as rs762079039; called by pindel, varscan2
- XAB2 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 193/483 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs202178945; called by muse, mutect2, varscan2
- ZAR1 | c.57dup p.C20Lfs*332 | Frame Shift Ins (INS) | VAF 236/505 reads (47%) | catalogued as rs757396573; called by mutect2, varscan2
- ZBED9 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 321/631 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs931069099; called by muse, mutect2, varscan2
- ZBTB40 | c.792dup p.L265Tfs*8 | Frame Shift Ins (INS) | VAF 112/230 reads (49%) | catalogued as rs775262758; called by mutect2, varscan2
- ZBTB7C | c.403dup p.E135Gfs*4 | Frame Shift Ins (INS) | VAF 152/446 reads (34%) | catalogued as rs747456682; called by mutect2, varscan2
- ZC3H14 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs1435099944, COSV51774604; called by muse, mutect2, varscan2
- ZFHX4 | c.6162_6165del p.P2056Hfs*26 | Frame Shift Del (DEL) | VAF 117/388 reads (30%) | catalogued as rs1554575033; called by pindel, varscan2*
- ZFP28 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 222/493 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100019617; called by muse, mutect2, varscan2
- ZFP82 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 436/657 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs908269233, COSV101089295; called by muse, mutect2, varscan2
- ZHX1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 245/813 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs747135351, COSV52876504; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs781576038; called by muse, mutect2, varscan2
- ZNF133 | c.911G>T p.G304V (on ENST00000316358 / NM_001352454.2; = p.G303V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/420 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60367852; called by muse, mutect2, varscan2
- ZNF208 | c.3213A>C p.R1071S | Missense Mutation (SNP) | VAF 208/490 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.029); catalogued as rs113038401, COSV68102901; called by mutect2, varscan2
- ZNF211 | c.1222C>T p.R408* (on ENST00000347302 / NM_198855.4; = p.R421* on NM_006385.5) | Nonsense Mutation (SNP) | VAF 272/559 reads (49%) | catalogued as rs775009360; called by muse, mutect2, varscan2
- ZNF234 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 392/393 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70603142; called by muse, mutect2, varscan2
- ZNF318 | c.3738del p.A1247Lfs*13 | Frame Shift Del (DEL) | VAF 166/482 reads (34%) | catalogued as COSV100545892; called by pindel, varscan2
- ZNF347 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 475/475 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV61968904; called by muse, mutect2, varscan2
- ZNF469 | c.9131G>A p.G3044D (on ENST00000437464; = p.G3072D on NM_001367624.2) | Missense Mutation (SNP) | VAF 42/680 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1024816121, COSV71258195; called by muse, mutect2
- ZNF831 | c.2785C>T p.L929F | Missense Mutation (SNP) | VAF 248/904 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1174650295, COSV100926119; called by muse, varscan2
- ZNF93 | c.183dup p.P62Tfs*8 | Frame Shift Ins (INS) | VAF 132/270 reads (49%) | catalogued as rs781728912; called by mutect2, varscan2
- ZSCAN20 | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 184/374 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100792770, COSV63682169; called by mutect2, varscan2
- ZSWIM3 | c.408del p.D137Tfs*16 | Frame Shift Del (DEL) | VAF 246/744 reads (33%) | catalogued as rs1426206799; called by mutect2, varscan2
- A2ML1 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 180/419 reads (43%) | called by mutect2, pindel, varscan2
- ABCA12 | c.2181dup p.A728Sfs*10 (on ENST00000272895 / NM_173076.3; = p.A410Sfs*10 on NM_015657.3) | Frame Shift Ins (INS) | VAF 362/507 reads (71%) | called by mutect2, pindel, varscan2
- ABCA3 | c.1572G>T p.E524D | Missense Mutation (SNP) | VAF 254/487 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, varscan2
- ABCC11 | c.4141C>A p.L1381M | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- ACAD10 | c.2181dup p.Y728Ifs*15 | Frame Shift Ins (INS) | VAF 225/587 reads (38%) | called by mutect2, pindel, varscan2
- ACAD10 | c.2932G>C p.A978P | Missense Mutation (SNP) | VAF 233/482 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSM1 | c.908T>A p.I303K | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ACSM2A | c.818T>C p.L273P (on ENST00000219054; = p.L194P on NM_001308169.2) | Missense Mutation (SNP) | VAF 217/427 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS10 | c.1699G>C p.V567L | Missense Mutation (SNP) | VAF 125/495 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADCY10 | c.4418A>G p.H1473R | Missense Mutation (SNP) | VAF 217/453 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADD1 | c.1213A>T p.K405* | Nonsense Mutation (SNP) | VAF 252/485 reads (52%) | called by muse, mutect2, varscan2
- ADGRA2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 22/668 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.088); called by muse, mutect2
- ADGRD2 | c.1459T>G p.S487A | Missense Mutation (SNP) | VAF 74/558 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRE1 | c.357C>G p.D119E | Missense Mutation (SNP) | VAF 21/492 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2
- ADGRG1 | c.1135T>C p.C379R | Missense Mutation (SNP) | VAF 236/486 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADGRL3 | c.2200G>A p.A734T (on ENST00000506720 / NM_001322402.2; = p.A666T on NM_015236.6) | Missense Mutation (SNP) | VAF 253/492 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- AKAP9 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALDH1L1 | c.393del p.S133Pfs*28 | Frame Shift Del (DEL) | VAF 143/412 reads (35%) | called by mutect2, pindel, varscan2
- ALG1 | c.398dup p.G134Rfs*4 | Frame Shift Ins (INS) | VAF 152/403 reads (38%) | called by mutect2, pindel, varscan2
- ALKBH7 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AMER2 | c.426del p.R143Efs*25 | Frame Shift Del (DEL) | VAF 101/266 reads (38%) | called by mutect2, pindel, varscan2
- AMER3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 496/497 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD1 | c.168del p.V57Cfs*65 | Frame Shift Del (DEL) | VAF 186/469 reads (40%) | called by mutect2, pindel, varscan2
- AMZ2 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ANK2 | c.8211del p.D2738Ifs*6 | Frame Shift Del (DEL) | VAF 157/405 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 324/654 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30A | c.683A>C p.N228T (on ENST00000611781; = p.N172T on NM_052997.2) | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ANKRD31 | c.1533dup p.G512Rfs*5 | Frame Shift Ins (INS) | VAF 113/264 reads (43%) | called by mutect2, varscan2
- ANKRD33 | c.680A>G p.Q227R (on ENST00000340970 / NM_001304459.2; = p.S419G on NM_182608.4) | Missense Mutation (SNP) | VAF 311/652 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36 | c.2498A>T p.D833V | Missense Mutation (SNP) | VAF 82/436 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANKRD60 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 232/716 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ANKRD60 | c.24del p.M9Cfs*108 | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | called by mutect2, pindel, varscan2
- ANKS6 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 206/423 reads (49%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APC2 | c.4245del p.R1416Gfs*164 | Frame Shift Del (DEL) | VAF 319/840 reads (38%) | called by mutect2, pindel, varscan2
- APOB | c.3565del p.M1189* | Frame Shift Del (DEL) | VAF 375/530 reads (71%) | called by mutect2, pindel, varscan2
- ARAP1 | c.4337T>G p.L1446R (on ENST00000393609 / NM_001040118.2; = p.L1201R on NM_015242.4) | Missense Mutation (SNP) | VAF 235/459 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ARHGAP17 | c.2479A>G p.T827A (on ENST00000289968 / NM_001006634.3; = p.T749A on NM_018054.6) | Missense Mutation (SNP) | VAF 126/473 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP20 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 96/454 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- ARHGAP20 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 96/436 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP24 | c.1697A>G p.E566G (on ENST00000395184 / NM_001025616.3; = p.E473G on NM_031305.3) | Missense Mutation (SNP) | VAF 234/461 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ARHGAP28 | c.1216T>C p.F406L (on ENST00000383472 / NM_001366230.1; = p.F247L on NM_001010000.3) | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGEF12 | c.3614T>C p.V1205A | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF28 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- ARID1A | c.6420dup p.F2141Lfs*9 | Frame Shift Ins (INS) | VAF 288/711 reads (41%) | called by mutect2, pindel, varscan2
- ASB4 | c.634del p.L212Wfs*59 | Frame Shift Del (DEL) | VAF 270/669 reads (40%) | called by mutect2, pindel, varscan2
- ASH1L | c.7430A>C p.K2477T (on ENST00000368346 / NM_001366177.2; = p.K2472T on NM_018489.3) | Missense Mutation (SNP) | VAF 150/336 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ASIC4 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ASTN2 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL3 | c.1763T>A p.I588N | Missense Mutation (SNP) | VAF 172/372 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ASXL3 | c.6099_6102delinsCGCCTC p.P2034Afs*47 | Frame Shift Ins (INS) | VAF 10/117 reads (9%) | called by pindel, varscan2*
- ATG5 | c.704del p.K235Rfs*4 | Frame Shift Del (DEL) | VAF 80/312 reads (26%) | called by mutect2, varscan2
- ATP2B4 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ATRNL1 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 234/544 reads (43%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN7L1 | c.2336dup p.R780Afs*2 | Frame Shift Ins (INS) | VAF 211/498 reads (42%) | called by mutect2, pindel, varscan2
- AWAT1 | c.95dup p.L32Ffs*64 | Frame Shift Ins (INS) | VAF 192/270 reads (71%) | called by mutect2, pindel, varscan2
- AZI2 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 153/332 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAIAP3 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 21/489 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.713); called by muse, mutect2
- BAIAP3 | c.2144T>C p.L715P | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- BAZ1A | c.597del p.E200Nfs*25 | Frame Shift Del (DEL) | VAF 117/316 reads (37%) | called by mutect2, pindel, varscan2
- BCHE | c.1791A>C p.E597D | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- BCHE | c.758del p.G253Dfs*9 | Frame Shift Del (DEL) | VAF 112/282 reads (40%) | called by mutect2, pindel*, varscan2
- BCKDHB | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- BLM | c.3651del p.K1217Nfs*62 | Frame Shift Del (DEL) | VAF 241/577 reads (42%) | called by mutect2, pindel, varscan2
- BMPR1B | c.1069T>G p.F357V | Missense Mutation (SNP) | VAF 131/253 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BNC2 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- BTAF1 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- C16orf46 | c.365dup p.E124Rfs*25 | Frame Shift Ins (INS) | VAF 217/582 reads (37%) | called by mutect2, pindel, varscan2
- C17orf50 | c.281del p.G94Afs*6 | Frame Shift Del (DEL) | VAF 298/774 reads (39%) | called by mutect2, pindel, varscan2
- C17orf80 | c.374dup p.N125Kfs*3 | Frame Shift Ins (INS) | VAF 135/358 reads (38%) | called by mutect2, pindel, varscan2
- C2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 322/668 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C5orf34 | c.1864del p.T622Pfs*? | Frame Shift Del (DEL) | VAF 261/539 reads (48%) | called by mutect2, pindel, varscan2
- C8orf34 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 713/967 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C8orf48 | c.484_485dup p.D162Efs*13 | Frame Shift Ins (INS) | VAF 125/283 reads (44%) | called by mutect2, varscan2
- CACHD1 | c.274dup p.I92Nfs*52 | Frame Shift Ins (INS) | VAF 106/212 reads (50%) | called by mutect2, varscan2
- CACYBP | c.331_332del p.R111Vfs*3 | Frame Shift Del (DEL) | VAF 40/217 reads (18%) | called by pindel, varscan2
- CAMK2B | c.1408C>A p.L470I | Missense Mutation (SNP) | VAF 168/321 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2D | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 147/273 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMSAP3 | c.2425del p.H809Tfs*180 | Frame Shift Del (DEL) | VAF 295/747 reads (39%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.3589A>G p.M1197V | Missense Mutation (SNP) | VAF 356/692 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CAPN14 | c.224dup p.E76Gfs*54 | Frame Shift Ins (INS) | VAF 186/497 reads (37%) | called by mutect2, pindel, varscan2
- CARD14 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 221/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARS2 | c.1607A>G p.H536R | Missense Mutation (SNP) | VAF 207/428 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 134/345 reads (39%) | called by mutect2, pindel, varscan2
- CASP14 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP8 | c.365T>G p.F122C (on ENST00000432109 / NM_033355.3; = p.F154C on NM_001228.4) | Missense Mutation (SNP) | VAF 365/367 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC151 | c.903A>G p.I301M | Missense Mutation (SNP) | VAF 263/528 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CCDC172 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CCDC174 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 247/508 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCDC18 | c.290dup p.P98Afs*4 | Frame Shift Ins (INS) | VAF 78/196 reads (40%) | called by mutect2, varscan2
- CCDC183 | c.215dup p.A73Gfs*117 | Frame Shift Ins (INS) | VAF 215/562 reads (38%) | called by mutect2, pindel, varscan2
- CCDC8 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 56/525 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CCDC81 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CCL22 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 168/384 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCT6A | c.835dup p.R279Kfs*9 | Frame Shift Ins (INS) | VAF 106/329 reads (32%) | called by pindel, varscan2
- CDH23 | c.522del p.S175Pfs*15 | Frame Shift Del (DEL) | VAF 284/729 reads (39%) | called by mutect2, pindel, varscan2
- CDH8 | c.55T>A p.L19I | Missense Mutation (SNP) | VAF 236/449 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK20 | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CDK5R2 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 156/662 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CDK5RAP1 | c.956A>T p.N319I (on ENST00000357886 / NM_001365728.1; = p.N305I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 345/533 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDRT15 | c.348_349dup p.A117Efs*114 | Frame Shift Ins (INS) | VAF 56/414 reads (14%) | called by mutect2, varscan2
- CDV3 | c.272_273del p.K91Rfs*3 | Frame Shift Del (DEL) | VAF 158/390 reads (41%) | called by mutect2, pindel, varscan2
- CELF3 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CEP162 | c.2581dup p.R861Kfs*7 | Frame Shift Ins (INS) | VAF 171/432 reads (40%) | called by mutect2, pindel, varscan2
- CEP350 | c.1168del p.S390Vfs*6 | Frame Shift Del (DEL) | VAF 58/304 reads (19%) | called by mutect2, pindel, varscan2
- CFAP46 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 206/565 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CFAP58 | c.2608dup p.M870Nfs*6 | Frame Shift Ins (INS) | VAF 149/404 reads (37%) | called by mutect2, pindel, varscan2
- CFAP61 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 215/474 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CFAP97 | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD1L | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2
- CHD8 | c.2699A>G p.Q900R (on ENST00000646647 / NM_001170629.2; = p.Q621R on NM_020920.4) | Missense Mutation (SNP) | VAF 183/350 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CHEK1 | c.783del p.D262Ifs*42 | Frame Shift Del (DEL) | VAF 119/300 reads (40%) | called by mutect2, pindel, varscan2
- CHGA | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 71/560 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHRM4 | c.121T>G p.S41A | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CILP | c.626T>C p.M209T | Missense Mutation (SNP) | VAF 189/190 reads (99%) | SIFT tolerated (0.36); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 116/300 reads (39%) | called by pindel, varscan2
- CLIC6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 200/434 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLOCK | c.2254T>G p.S752A | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- CLVS2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNKSR1 | c.873_876+37delinsCACAGGTACCTTCCCCTGCCGCCCCCCGACCTGCCTTCAGA p.X291_splice (on ENST00000374253 / NM_001297647.2; = p.X284_splice on NM_006314.3) | Splice Site (ONP) | VAF 19/237 reads (8%) | called by pindel, varscan2*
- CNTN1 | c.482del p.P161Hfs*14 | Frame Shift Del (DEL) | VAF 118/287 reads (41%) | called by mutect2, pindel, varscan2
- CNTN1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CNTN2 | c.451dup p.V151Gfs*6 | Frame Shift Ins (INS) | VAF 251/602 reads (42%) | called by mutect2, pindel, varscan2
- COL12A1 | c.1220T>C p.M407T | Missense Mutation (SNP) | VAF 220/443 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- COL18A1 | c.4564dup p.E1522Gfs*14 (on ENST00000359759 / NM_130444.3; = p.E1287Gfs*14 on NM_030582.4) | Frame Shift Ins (INS) | VAF 216/548 reads (39%) | called by mutect2, pindel, varscan2
- COL1A1 | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 258/521 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- COL20A1 | c.1594T>G p.Y532D | Missense Mutation (SNP) | VAF 294/933 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.1622dup p.G542Wfs*23 | Frame Shift Ins (INS) | VAF 173/758 reads (23%) | called by pindel, varscan2
- COL27A1 | c.2447dup p.G817Wfs*8 | Frame Shift Ins (INS) | VAF 173/636 reads (27%) | called by pindel, varscan2
- COL5A1 | c.4050del p.G1351Efs*137 | Frame Shift Del (DEL) | VAF 227/574 reads (40%) | called by mutect2, pindel, varscan2
- COL5A3 | c.4726dup p.C1576Lfs*18 | Frame Shift Ins (INS) | VAF 258/577 reads (45%) | called by mutect2, pindel, varscan2
- COLEC12 | c.2182T>G p.F728V | Missense Mutation (SNP) | VAF 185/412 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COLGALT1 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 121/537 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- COPS3 | c.537dup p.H180Tfs*20 | Frame Shift Ins (INS) | VAF 161/439 reads (37%) | called by mutect2, pindel, varscan2
- COX7A1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 54/956 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPA4 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPEB3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 275/535 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CPLANE1 | c.9279del p.K3093Nfs*16 | Frame Shift Del (DEL) | VAF 380/763 reads (50%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.362C>T p.A121V (on ENST00000425232; = p.P229S on NM_023073.3) | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CR1 | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 43/323 reads (13%) | called by muse, mutect2, varscan2
- CREB5 | c.291+1dup | Frame Shift Ins (INS) | VAF 118/298 reads (40%) | called by mutect2, pindel, varscan2
- CRLF1 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 190/391 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRYBG2 | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 356/667 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRYGA | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 158/413 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, varscan2
- CSMD3 | c.1790A>G p.E597G (on ENST00000297405 / NM_001363185.1; = p.E493G on NM_052900.3) | Missense Mutation (SNP) | VAF 37/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSRNP1 | c.1249C>A p.L417M | Missense Mutation (SNP) | VAF 325/579 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CTTN | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 40/312 reads (13%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2039C>G p.T680S | Missense Mutation (SNP) | VAF 245/246 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CYP4A11 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 152/323 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- D2HGDH | c.907C>A p.L303M | Missense Mutation (SNP) | VAF 39/491 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DACH1 | c.499dup p.L167Pfs*20 | Frame Shift Ins (INS) | VAF 216/364 reads (59%) | called by pindel, varscan2
- DAPK1 | c.3286A>G p.S1096G | Missense Mutation (SNP) | VAF 261/522 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DBF4 | c.879dup p.G294Rfs*4 | Frame Shift Ins (INS) | VAF 109/287 reads (38%) | called by mutect2, pindel, varscan2
- DBNL | c.1247G>A p.G416D (on ENST00000448521 / NM_001014436.3; = p.G417D on NM_014063.7) | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DDX42 | c.1524del p.A509Pfs*6 | Frame Shift Del (DEL) | VAF 253/520 reads (49%) | called by mutect2, varscan2
- DENND6B | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 240/468 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX29 | c.369dup p.L124Ifs*14 | Frame Shift Ins (INS) | VAF 108/257 reads (42%) | called by mutect2, pindel, varscan2
- DHX38 | c.1808del p.G603Efs*22 | Frame Shift Del (DEL) | VAF 113/272 reads (42%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.3079T>C p.C1027R | Missense Mutation (SNP) | VAF 170/354 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIAPH1 | c.2030del p.P677Hfs*91 | Frame Shift Del (DEL) | VAF 100/219 reads (46%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.1070A>T p.D357V | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DLG4 | c.1844C>G p.S615C (on ENST00000399506 / NM_001321075.3; = p.S658C on NM_001365.4) | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP2 | c.2285A>G p.K762R | Missense Mutation (SNP) | VAF 228/432 reads (53%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- DMAP1 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 153/307 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH17 | c.11122G>A p.D3708N | Missense Mutation (SNP) | VAF 264/503 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DNAH5 | c.5563del p.I1855Sfs*16 | Frame Shift Del (DEL) | VAF 455/844 reads (54%) | called by mutect2, pindel, varscan2
- DNAH9 | c.6400-1G>T p.X2134_splice | Splice Site (SNP) | VAF 191/191 reads (100%) | called by muse, mutect2, varscan2
- DNM1L | c.2003dup p.A669Gfs*8 (on ENST00000549701 / NM_012062.5; = p.A632Gfs*8 on NM_005690.4) | Frame Shift Ins (INS) | VAF 114/247 reads (46%) | called by mutect2, pindel, varscan2
- DOCK3 | c.4600C>T p.H1534Y | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2
- DPEP3 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- DPP3 | c.1501A>G p.T501A | Missense Mutation (SNP) | VAF 192/401 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DSG3 | c.172T>C p.C58R | Missense Mutation (SNP) | VAF 164/323 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DUSP22 | c.475_476dup p.L159Ffs*18 | Frame Shift Ins (INS) | VAF 112/402 reads (28%) | called by mutect2, pindel, varscan2
- DVL3 | c.371dup p.S125Qfs*8 | Frame Shift Ins (INS) | VAF 168/278 reads (60%) | called by pindel, varscan2
- DYNC1LI2 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DYNC2LI1 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- E2F8 | c.1142dup p.N381Kfs*27 | Frame Shift Ins (INS) | VAF 179/307 reads (58%) | called by pindel, varscan2
- EDEM2 | c.1410dup p.Y471Vfs*51 | Frame Shift Ins (INS) | VAF 251/871 reads (29%) | called by mutect2, pindel, varscan2
- EHBP1 | c.2156A>C p.D719A | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EHMT1 | c.244del p.Q82Rfs*7 | Frame Shift Del (DEL) | VAF 276/625 reads (44%) | called by mutect2, pindel, varscan2
- EIF3B | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 160/299 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EIF3L | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- EIPR1 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.122); called by muse, mutect2
- ELFN1 | c.1786C>A p.P596T | Missense Mutation (SNP) | VAF 337/662 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELP1 | c.3741G>C p.E1247D | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EN1 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 226/429 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ENTPD4 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 184/376 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EOMES | c.579del p.G194Afs*94 | Frame Shift Del (DEL) | VAF 311/800 reads (39%) | called by mutect2, pindel, varscan2
- EPC1 | c.1266C>G p.N422K | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, varscan2
- EPHA5 | c.242del p.N81Mfs*24 | Frame Shift Del (DEL) | VAF 129/336 reads (38%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6121T>C p.Y2041H | Missense Mutation (SNP) | VAF 628/1193 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPS15L1 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 287/581 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESYT3 | c.328-1G>T p.X110_splice | Splice Site (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2, varscan2
- EWSR1 | c.250del p.Q84Rfs*80 | Frame Shift Del (DEL) | VAF 203/489 reads (42%) | called by mutect2, pindel, varscan2
- EXOC6 | c.227_234del p.A76Gfs*4 | Frame Shift Del (DEL) | VAF 77/262 reads (29%) | called by mutect2, pindel, varscan2
- EXOC8 | c.901C>G p.P301A | Missense Mutation (SNP) | VAF 248/585 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EYS | c.1475del p.K492Sfs*23 | Frame Shift Del (DEL) | VAF 106/277 reads (38%) | called by pindel, varscan2
- FAM117A | c.221del p.P74Qfs*57 | Frame Shift Del (DEL) | VAF 68/365 reads (19%) | called by mutect2, pindel, varscan2
- FAM133B | c.479dup p.K161Efs*9 | Frame Shift Ins (INS) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- FAM155A | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 205/417 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM155B | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 224/225 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- FAM184B | c.1193A>T p.E398V | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FAM220A | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 15/555 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2
- FANCM | c.1031dup p.N344Kfs*23 | Frame Shift Ins (INS) | VAF 100/253 reads (40%) | called by mutect2, pindel, varscan2
- FBN2 | c.4579G>T p.G1527* | Nonsense Mutation (SNP) | VAF 138/317 reads (44%) | called by muse, mutect2, varscan2
- FBN2 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 168/331 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FBXO10 | c.97T>C p.W33R | Missense Mutation (SNP) | VAF 199/422 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FCRL3 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 173/330 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL5 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- FES | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FGF13 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 229/230 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FHL5 | c.138dup p.P47Tfs*3 | Frame Shift Ins (INS) | VAF 96/236 reads (41%) | called by mutect2, pindel, varscan2
- FNDC10 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2
- FNIP2 | c.187T>G p.L63V | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- FOCAD | c.4796A>C p.N1599T | Missense Mutation (SNP) | VAF 192/358 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXD3 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 290/566 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXK1 | c.1523C>A p.P508H | Missense Mutation (SNP) | VAF 358/755 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FOXN2 | c.812del p.K271Rfs*22 | Frame Shift Del (DEL) | VAF 92/255 reads (36%) | called by mutect2, pindel, varscan2
- FOXRED2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 339/672 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FUZ | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 406/407 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GAB1 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB2 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRG2 | c.471dup p.A158Sfs*2 | Frame Shift Ins (INS) | VAF 157/225 reads (70%) | called by mutect2, pindel, varscan2
- GAK | c.194_195del p.E65Vfs*10 | Frame Shift Del (DEL) | VAF 44/410 reads (11%) | called by pindel, varscan2
- GAL3ST3 | c.1012dup p.D338Gfs*31 | Frame Shift Ins (INS) | VAF 185/466 reads (40%) | called by mutect2, pindel, varscan2
- GALC | c.273T>A p.F91L | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALNT8 | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 286/287 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GAREM2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 228/476 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GDA | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 150/304 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GGCT | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.422); called by muse, mutect2
- GHDC | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 237/504 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GIGYF1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 279/537 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GINM1 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 174/357 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJB7 | c.602dup p.L201Ffs*8 | Frame Shift Ins (INS) | VAF 125/321 reads (39%) | called by mutect2, pindel, varscan2
- GNAS | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 155/492 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GNPNAT1 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 133/329 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GNPTAB | c.3005T>C p.M1002T | Missense Mutation (SNP) | VAF 181/367 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GPR153 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHPR | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 153/348 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, varscan2
- GRIN2D | c.1432dup p.R478Pfs*166 | Frame Shift Ins (INS) | VAF 348/485 reads (72%) | called by mutect2, pindel, varscan2
- GRIP1 | c.3202G>A p.V1068M (on ENST00000359742 / NM_001379345.1; = p.V1016M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 190/418 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIP2 | c.1913T>C p.V638A (on ENST00000619221; = p.V541A on NM_001080423.4) | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- GRXCR1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 147/283 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRXCR1 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GUCY1A1 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- H4C4 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 172/330 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- HBEGF | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 254/524 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HDC | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HELLS | c.385del p.R129Efs*54 | Frame Shift Del (DEL) | VAF 114/265 reads (43%) | called by mutect2, pindel, varscan2
- HERC6 | c.1988del p.K663Rfs*27 | Frame Shift Del (DEL) | VAF 153/361 reads (42%) | called by mutect2, pindel, varscan2
- HFM1 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HGF | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HGH1 | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 875/1736 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HINFP | c.1355C>A p.A452D | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2
- HLA-A | c.802T>C p.W268R | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 156/432 reads (36%) | called by pindel, varscan2
- HMCN1 | c.14412G>T p.Q4804H | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HMX1 | c.300del p.G101Vfs*124 | Frame Shift Del (DEL) | VAF 100/204 reads (49%) | called by mutect2, varscan2
- HMX1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 221/491 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HR | c.244dup p.Q82Pfs*44 | Frame Shift Ins (INS) | VAF 312/776 reads (40%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.663del p.F221Lfs*10 | Frame Shift Del (DEL) | VAF 99/240 reads (41%) | called by mutect2, pindel, varscan2
- HSP90B1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 205/442 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA2 | c.1691A>G p.K564R | Missense Mutation (SNP) | VAF 194/412 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HSPA9 | c.878_879dup p.T294Rfs*6 | Frame Shift Ins (INS) | VAF 102/206 reads (50%) | called by mutect2, varscan2
- IBTK | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ICAM5 | c.923del p.G308Afs*10 | Frame Shift Del (DEL) | VAF 234/624 reads (38%) | called by mutect2, pindel, varscan2
- IFNK | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 171/352 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNLR1 | c.447dup p.C150Lfs*10 | Frame Shift Ins (INS) | VAF 299/780 reads (38%) | called by mutect2, pindel, varscan2
- IGFBPL1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 210/424 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, varscan2
- IGHG3 | c.1040G>T p.W347L | Missense Mutation (SNP) | VAF 116/624 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGSF10 | c.6089A>G p.H2030R | Missense Mutation (SNP) | VAF 215/426 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IL12RB2 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 206/472 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- IL18BP | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 347/661 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ILVBL | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 68/493 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- IMPG2 | c.3451T>C p.S1151P | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- INPP5B | c.1617del p.V540* (on ENST00000373023; = p.V460* on NM_005540.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 255/623 reads (41%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- INTS12 | c.41dup p.L14Ffs*12 | Frame Shift Ins (INS) | VAF 124/282 reads (44%) | called by mutect2, varscan2
- IP6K1 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 240/520 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- IQCN | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 260/562 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IQSEC3 | c.1364C>T p.A455V (on ENST00000538872 / NM_001170738.2; = p.A152V on NM_015232.1) | Missense Mutation (SNP) | VAF 262/262 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IRAG2 | c.2301A>C p.K767N | Missense Mutation (SNP) | VAF 178/437 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- IRS2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 259/513 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- IRX1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ITFG1 | c.1445dup p.N482Kfs*32 | Frame Shift Ins (INS) | VAF 107/259 reads (41%) | called by mutect2, pindel, varscan2
- ITGB1BP1 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 209/424 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ITIH5 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 118/119 reads (99%) | SIFT tolerated (0.75); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ITPKC | c.1058dup p.S354Qfs*14 | Frame Shift Ins (INS) | VAF 575/812 reads (71%) | called by mutect2, pindel, varscan2
- ITPR3 | c.4750A>G p.N1584D | Missense Mutation (SNP) | VAF 485/701 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ITPRIPL2 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 249/548 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KALRN | c.1099A>G p.N367D | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KANK3 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 228/478 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT6B | c.433_435del p.N145del | In Frame Del (DEL) | VAF 215/492 reads (44%) | called by pindel, varscan2
- KBTBD2 | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 236/431 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNJ15 | c.227T>C p.M76T | Missense Mutation (SNP) | VAF 260/501 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KCNJ16 | c.1137dup p.V380Cfs*5 | Frame Shift Ins (INS) | VAF 229/573 reads (40%) | called by mutect2, pindel, varscan2
- KCNJ2 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 217/419 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCNJ4 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 356/757 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK3 | c.827del p.G276Vfs*52 | Frame Shift Del (DEL) | VAF 283/549 reads (52%) | called by mutect2, varscan2
- KCNQ2 | c.2227C>T p.P743S (on ENST00000359125 / NM_172107.4; = p.P715S on NM_004518.6) | Missense Mutation (SNP) | VAF 453/1475 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNQ2 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 220/667 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- KCNQ5 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 268/638 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, mutect2
822 further variants in this file (437 protein-altering or splice-affecting, 327 silent, 58 other) are not listed here.
